Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JM-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

ICD-0.3
Carcinoma, papillary
renal cell 8260/3
Site: O Kidney NOS C64.9
J 4/28/14

Final Diagnosis

- A. LEFT KIDNEY:
Renal cell carcinoma, papillary type 1, Fuhrman nuclear grade 2, two separate foci, confined to kidney measuring 0.7 cm and 2.5 x 2 x 1.7 cm. (See Key Pathological Findings and See Comment).
Resection margins (ureteral, vascular and peripheral soft tissue), free of tumor.
Multiple papillary adenomas (17).
Acquired cystic disease of kidney.
Pathologic stage (for both foci): pT1a NX MX.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Comment

Immunohistochemical stains performed on the larger renal cell carcinoma, shows the tumor cells to be positive for vimentin, cytokeratin 7, AMACR, and focally positive for CD10. The immunoprofile supports the above diagnosis. Immunohistochemical stains performed on papillary adenomas show positive staining for cytokeratin 7, AMACR, and focal positivity for CD10. Immunohistochemical stains performed on one of the cystic lesions shows lining epithelial cells to be focally and weakly positive for CK7 and negative for CD31.

Key Pathological Findings

Tumor type:	Renal cell carcinoma, papillary type 1, two separate foci
Nuclear grade:	2
Pattern of growth:	Papillary
Tumor size:	2.5 x 2 x 1.7 cm and 0.7 cm
Renal capsule invasion:	Not identified
Invasion of perinephric adipose tissue:	Not identified
Renal vein invasion:	Not identified
Surgical margins:	Free of tumor
Ureteral and vascular margins:	Free of tumor
Lymphovascular invasion:	Not identified
Non-neoplastic kidney:	Acquired cystic disease of kidney and changes consistent with patient's history of end-stage renal disease
Adrenal gland:	Not identified
Lymph nodes:	Not identified
Pathologic stage:	pT1a NX MX

Specimen(s) Received

[page 2 of 2]
A LEFT KIDNEY

Clinical History

Endstage renal polyarteritis nodosa with living related donor right renal transplant in

Preoperative Diagnosis

Left kidney mass.

Gross Description

A. The specimen received fresh labeled "left kidney". The specimen consists of an 82 gram, 5 x 3.5 x 2.8 cm kidney which is surrounded by perinephric adipose tissue ranging from 0.1 to 0.8 cm in thickness. Prior to sectioning the perinephric adipose tissue resection margin is inked black. There is a 2-cm length of ureter attached to the kidney which is grossly unremarkable. The specimen is serially sectioned to reveal an irregular to roughly soft-to-rubbery intraparenchymal tumor which measures 2.5 x 2 x 1.7 cm. The tumor involves the cortex and medulla of the superior lateral aspect of the kidney. The tumor bulges but does not appear to extend through the renal capsule and is within 0.3 cm of the closest perinephric adipose tissue resection margin. The cut surface of the tumor is pale-yellow to pink, lobulated, without evidence of necrosis or hemorrhage. Neither calices nor renal pelvis are involved by the tumor. The renal artery and vein and their branches do not appear to be involved by the tumor. At least 17 satellite intraparenchymal and subcapsular tumor nodules are identified ranging from 0.1 to 0.7 cm in greatest dimension. There are also several subcapsular and intraparenchymal cysts which range from 0.3 to 0.6 cm in greatest dimension. The cysts are filled with transparent fluid. The remaining renal parenchyma is tan-red-brown. The atrophic cortex ranges from 0.2 to 0.5 cm in thickness. Urothelium of the calices, renal pelvis, and the portion of ureter, is tan, smooth and glistening. No lymph nodes are found within hilar adipose tissue. No adrenal gland is identified within superior pole of the specimen. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 16 cassettes as follows:

- A1: Resection margin of the renal artery
- A2: Cross sections of the proximal portion of ureter
- A3: Renal pelvis
- A4-A8: Representative sections of the tumor overlying renal capsule and adjacent

perinephric adipose tissue

A9-A16: Additional sections of the renal parenchyma with multiple satellite tumor nodules and subcapsular and intraparenchymal cysts.

- A17: Resection margins of ureter and renal vein

Representative sections of the specimen are submitted to the Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file 3ca47439-a473-4f04-b52a-5fd61f0c81b1 (TCGA-2Z-A9JM.B3ABA98A-0D0D-493C-9F20-E8B7E3A935EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).